Gene-level copy-number profile of specimen HCM-SANG-1329-C15-85A-01D-A80T-32 from HCMI case HCM-SANG-1329-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G3.
Specimen HCM-SANG-1329-C15-85A-01D-A80T-32: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file be17f9c4-6264-47f9-b2f8-f7279e77f2ec.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-1329-C15-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,720 have no estimate.
https://portal.gdc.cancer.gov/files/d5117969-5ed1-470f-8f24-2f5a28dc4988

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,947; copy number 2: 26,937; copy number 3: 16,917; copy number 4: 10,925; copy number 5: 115; copy number 6: 61; copy number 8: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 177 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:767,382–768,930, 1 gene, copy number 8: BRD9P2.
- chr5:43,515,274–43,525,310, 1 gene, copy number 5 (within-gene range 4–5): AC114956.1.
- chr5:43,571,594–44,658,569, 10 genes, copy number 5: NNT-AS1, AC010435.1, AMD1P3, NNT, RPL29P12, AC104119.1, RNU6-381P, FGF10, FGF10-AS1, LINC02224.
- chr9:61,190,003–61,945,136, 20 genes, copy number 5: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P, AL935212.3, FAM242D, Y_RNA, AL935212.1, AL935212.2, RN7SL722P, AL391987.2, AL391987.1, AL391987.4, AL391987.3, Y_RNA, FAM242E, CR769775.1.
- chr9:62,856,999–62,898,095, 1 gene, copy number 5 (within-gene range 4–5): LERFS.
- chr9:62,888,535–63,703,755, 12 genes, copy number 5: FGF7P8, AL512625.1, CNTNAP3P1, AL591379.2, BMS1P9, AL591379.1, AQP7P4, BMS1P10, AQP7P1, AL845321.1, AL591438.1, AL591438.2.
- chr10:3,911,889–3,935,817, 1 gene, copy number 6: LINC02660.
- chr17:54,899,387–54,961,956, 1 gene, copy number 5 (within-gene range 4–5): TOM1L1.
- chr19:27,638,483–34,066,283, 130 genes, copy number 5–6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,947. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
